Somatic mutation profile of tumor specimen TCGA-WC-A87U-01A (aliquot TCGA-WC-A87U-01A-11D-A39W-08) from TCGA case TCGA-WC-A87U, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.7 years (26,933 days).
Specimen TCGA-WC-A87U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83a75f1d-2dfb-4ac1-b3fc-2f11c0816a0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A87U-10A (Blood Derived Normal), aliquot TCGA-WC-A87U-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82d90f82-708c-41f6-a47b-62e30d3c5cb9

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 13/13 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63309310, COSV63309316; called by muse, mutect2, varscan2
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 40/86 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEP95 | c.1928A>C p.K643T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs185494775; called by muse, mutect2, varscan2
- PLD2 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779094449; called by muse, mutect2, varscan2
- SLC26A5 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs773574721, COSV59702635; called by muse, mutect2, varscan2
- SLC2A8 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1461206142; called by muse, mutect2, varscan2
- ASXL3 | c.3518C>T p.A1173V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR87 | c.303T>G p.D101E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- PPP1R3A | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SETX | c.6199C>T p.H2067Y | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- DHRS7B | c.699C>T p.T233= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as rs577733383; called by muse, mutect2, varscan2
- FKBP9 | c.1020G>A p.G340= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- NBEAL2 | c.4155G>A p.Q1385= | Silent (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
